CCDI case PBBYVV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9af270f3-2b2e-472c-a7fb-5ac2537826b5

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.4 years (868 days).

Biospecimens (3 samples)
- Sample 0DLA0Y: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLA1X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DLA2S: Tissue type: Tumor; Specimen type: Solid Tissue.
